Somatic mutation profile of tumor specimen ALCH-B211-TTP1-A (aliquot ALCH-B211-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B211, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 70.5 years (25,755 days).
Specimen ALCH-B211-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57900fbb-5f99-466f-8519-e437ba1aa163.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B211-NB1-A (Blood Derived Normal), aliquot ALCH-B211-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78b1a7b6-cceb-4550-bb1c-dcb5138aafe2

The open-access MAF lists 328 somatic variants for this specimen: 226 protein-altering or splice-affecting, 61 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 191, Silent 61, Nonsense Mutation 22, Intron 12, RNA 12, 3'UTR 7, 3'Flank 5, Frame Shift Del 4, Splice Site 4, Frame Shift Ins 3, 5'UTR 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RYR2 | c.1250G>T p.R417L | Missense Mutation (SNP) | VAF 44/331 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs751428303, COSV63688268, COSV63692084; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 41/259 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ABCA3 | c.4465C>T p.R1489C | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs773525683, COSV100068826; called by muse, mutect2, varscan2
- ADAM32 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 30/327 reads (9%) | catalogued as rs1055057859; called by muse, mutect2
- ADRB1 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV65167632; called by muse, mutect2, varscan2
- AHNAK | c.13108G>T p.G4370C | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57210894; called by muse, mutect2, varscan2
- ALB | c.1165G>C p.D389H | Missense Mutation (SNP) | VAF 64/454 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as rs77187142, CM870082; ClinVar: other; called by muse, mutect2, varscan2
- ARHGAP28 | c.1271G>A p.G424E (on ENST00000383472 / NM_001366230.1; = p.G265E on NM_001010000.3) | Missense Mutation (SNP) | VAF 51/303 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1369346560, COSV51632452; called by muse, mutect2, varscan2
- BRINP1 | c.2008C>A p.R670S | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV56314239; called by muse, mutect2, varscan2
- CCND1 | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 96/120 reads (80%) | catalogued as COSV99919608; called by muse, mutect2, varscan2
- CCT3 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 51/369 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs773818166, COSV55290883; called by muse, mutect2, varscan2
- CDC42BPG | c.1300C>T p.Q434* | Nonsense Mutation (SNP) | VAF 49/134 reads (37%) | catalogued as COSV100712105, COSV61349570; called by muse, mutect2, varscan2
- CDH9 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.532); catalogued as rs555002432, COSV50283851; called by muse, mutect2, varscan2
- CFAP300 | c.44G>A p.R15K | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.288); catalogued as rs1379024098; called by muse, mutect2, varscan2
- CLCN7 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1237646633; called by muse, mutect2, varscan2
- CTBP1 | c.1024C>A p.R342= | Splice Region (SNP) | VAF 10/46 reads (22%) | catalogued as CM164204; called by muse, mutect2, varscan2
- DDX11 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 64/474 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.183); catalogued as rs757994608; called by muse, mutect2, varscan2
- DDX42 | c.1870G>A p.V624I | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs753057398, COSV63790824; called by muse, mutect2, varscan2
- DGKK | c.3436G>A p.V1146I | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as rs371705438; called by muse, mutect2, varscan2
- DUSP22 | c.385G>C p.V129L | Missense Mutation (SNP) | VAF 29/281 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60531870; called by muse, mutect2, varscan2
- EPHA6 | c.1407C>A p.D469E | Missense Mutation (SNP) | VAF 31/387 reads (8%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.652); catalogued as rs1353411480; called by muse, mutect2
- ERMARD | c.1317+1G>T p.X439_splice | Splice Site (SNP) | VAF 16/111 reads (14%) | catalogued as rs369772652; called by muse, mutect2, varscan2
- FAT1 | c.10042G>A p.A3348T | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV71676713; called by muse, mutect2, varscan2
- FUT9 | c.645C>G p.I215M | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56145104, COSV56148122; called by muse, varscan2
- GAK | c.2980C>A p.P994T | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV58505128; called by muse, mutect2, varscan2
- GHRHR | c.352C>A p.L118M | Missense Mutation (SNP) | VAF 105/553 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs773339685, COSV58198307; called by muse, mutect2, varscan2
- GORAB | c.223G>C p.V75L | Missense Mutation (SNP) | VAF 64/439 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV63026669; called by muse, mutect2, varscan2
- H2BC17 | c.63G>C p.K21N | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.847); catalogued as rs767028565; called by muse, mutect2
- HS3ST4 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as rs1302755378; called by muse, mutect2
- ITGB6 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs755729961, COSV51794145; called by muse, mutect2, varscan2
- JPH2 | c.1123C>G p.R375G | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV65901949; called by muse, mutect2, varscan2
- KANSL1 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.79); catalogued as COSV52267073; called by muse, mutect2
- KIAA1109 | c.2932A>G p.I978V | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1329730121; called by muse, mutect2, varscan2
- KRT73 | c.856T>C p.S286P | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59839176; called by muse, mutect2, varscan2
- LILRA2 | c.463T>C p.C155R | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs1332050504; called by muse, mutect2
- LILRB1 | c.577T>C p.C193R (on ENST00000427581; = p.C157R on NM_006669.6) | Missense Mutation (SNP) | VAF 43/332 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs183166312; called by muse, mutect2, varscan2
- LIN7C | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 26/173 reads (15%) | catalogued as rs1287674505, COSV53415293, COSV53416696; called by muse, mutect2, varscan2
- LRRTM4 | c.962C>A p.P321H | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1382799878; called by muse, mutect2, varscan2
- MKRN3 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 45/336 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.375); catalogued as rs776896408; called by muse, mutect2, varscan2
- MUC16 | c.7970C>A p.P2657Q | Missense Mutation (SNP) | VAF 46/269 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV67468482; called by muse, mutect2, varscan2
- MUC16 | c.6220T>C p.S2074P | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); catalogued as rs1289453326; called by muse, mutect2, varscan2
- MYCT1 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 38/219 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs201459322; called by muse, mutect2, varscan2
- MYO1H | c.2498A>G p.Q833R | Missense Mutation (SNP) | VAF 41/326 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1424104462; called by muse, mutect2, varscan2
- NDN | c.20A>G p.D7G | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as COSV59359407; called by muse, mutect2, varscan2
- NDN | c.19G>T p.D7Y | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); catalogued as COSV59360269; called by muse, mutect2, varscan2
- NGEF | c.200G>C p.R67P | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.693); catalogued as rs776864089; called by muse, mutect2, varscan2
- NME8 | c.1404G>T p.Q468H | Missense Mutation (SNP) | VAF 51/326 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs759095592, COSV52255271; called by muse, mutect2, varscan2
- NME8 | c.1621C>A p.P541T | Missense Mutation (SNP) | VAF 66/436 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1224442590; called by muse, mutect2, varscan2
- NMS | c.314G>T p.R105L | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV65258561, COSV65258964; called by muse, mutect2, varscan2
- NPHS2 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 87/631 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1472510122, CM161437; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPY1R | c.664G>T p.G222C | Missense Mutation (SNP) | VAF 37/273 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs1365581991; called by muse, mutect2, varscan2
- NUP188 | c.2458G>A p.V820I | Missense Mutation (SNP) | VAF 46/271 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs370614354; called by muse, mutect2, varscan2
- OR10A5 | c.785G>T p.W262L | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100203470; called by muse, mutect2, varscan2
- OR5D14 | c.738C>A p.H246Q | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59457866; called by muse, mutect2
- PHKB | c.785G>A p.W262* | Nonsense Mutation (SNP) | VAF 102/653 reads (16%) | catalogued as rs1277579547; called by muse, mutect2, varscan2
- PKHD1L1 | c.7676C>T p.P2559L | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs746424993; called by muse, mutect2, varscan2
- PLCH1 | c.609G>T p.E203D (on ENST00000340059 / NM_001130960.2; = p.E215D on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58210854; called by muse, mutect2
- PPM1H | c.1074G>T p.W358C | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99956742; called by muse, mutect2, varscan2
- PTPRK | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 90/593 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs766461424; called by muse, mutect2, varscan2
- SCN2A | c.5623C>T p.L1875F | Missense Mutation (SNP) | VAF 50/297 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1553463764; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERPINA3 | c.832C>A p.L278I | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1262544040; called by muse, mutect2, varscan2
- SKOR2 | c.447C>A p.H149Q | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV68550684; called by muse, mutect2, varscan2
- SLC26A5 | c.1342C>A p.L448M | Missense Mutation (SNP) | VAF 94/619 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59700204; called by muse, mutect2, varscan2
- SLC32A1 | c.548G>T p.R183L | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54148107, COSV99462612; called by muse, mutect2, varscan2
- SLC4A10 | c.484C>A p.L162I | Missense Mutation (SNP) | VAF 36/299 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV55764216; called by muse, mutect2, varscan2
- SLITRK3 | c.2642G>A p.G881D | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.129); catalogued as COSV99578596; called by muse, mutect2
- SNAP91 | c.2567C>T p.P856L | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs781354659; called by muse, mutect2, varscan2
- SSR3 | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 22/142 reads (15%) | catalogued as rs1426771928, COSV99411094; called by muse, mutect2, varscan2
- STAB2 | c.3658C>T p.R1220C | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745972632, COSV101186240; called by muse, mutect2, varscan2
- STX2 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 43/265 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs201987693, COSV55433348; called by muse, mutect2, varscan2
- TGFBR2 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 102/460 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs1199303428; called by muse, mutect2, varscan2
- THEMIS | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373934545, COSV64069016; called by muse, mutect2
- TMEM214 | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.412); catalogued as COSV53191807; called by muse, mutect2, varscan2
- TRHDE | c.905C>G p.S302C | Missense Mutation (SNP) | VAF 94/498 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99038832; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1115G>T p.C372F | Missense Mutation (SNP) | VAF 19/297 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371019011; called by muse, mutect2
- TRMT6 | c.961A>T p.M321L | Missense Mutation (SNP) | VAF 76/466 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV52543408; called by muse, mutect2, varscan2
- USH2A | c.10132C>A p.P3378T | Missense Mutation (SNP) | VAF 40/276 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1429944281, COSV56368490; called by muse, mutect2, varscan2
- XDH | c.3593G>T p.G1198V | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65151194; called by muse, mutect2, varscan2
- ZBED5 | c.1937C>T p.T646M | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs1245259689; called by muse, mutect2, varscan2
- ZDHHC13 | c.1746G>T p.Q582H | Missense Mutation (SNP) | VAF 97/649 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV67981626; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2708G>T p.R903L | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.213); catalogued as COSV60155530; called by muse, mutect2, varscan2
- ZNF275 | c.344T>C p.L115P | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.063); catalogued as rs1556961661; called by muse, mutect2, varscan2
- ABCC12 | c.3971T>A p.V1324D | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ABCC6 | c.2453C>A p.P818H | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- AC013489.1 | c.1336G>T p.G446C | Missense Mutation (SNP) | VAF 61/434 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- AHSA1 | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 94/436 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD18B | c.2339A>G p.N780S | Missense Mutation (SNP) | VAF 164/462 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- ANO3 | c.2023G>A p.D675N | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- ARID1B | c.4036_4037dup p.G1347Efs*89 | Frame Shift Ins (INS) | VAF 21/152 reads (14%) | called by mutect2, pindel, varscan2
- ASAH2 | c.687+2T>A p.X229_splice | Splice Site (SNP) | VAF 24/199 reads (12%) | called by muse, mutect2, varscan2
- ASXL2 | c.1785G>T p.Q595H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ATG2B | c.3439A>T p.I1147F | Missense Mutation (SNP) | VAF 64/414 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATP11B | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 41/684 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.099); called by muse, mutect2
- ATXN7 | c.2373G>A p.M791I | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- BIRC6 | c.3461A>T p.N1154I | Missense Mutation (SNP) | VAF 39/305 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- BTBD7 | c.2989A>T p.T997S | Missense Mutation (SNP) | VAF 58/328 reads (18%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTBD9 | c.1231A>T p.N411Y | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- C8orf34 | c.572C>G p.S191C | Missense Mutation (SNP) | VAF 28/348 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2
- CCDC116 | c.152C>T p.T51I | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CDH23 | c.7345G>C p.A2449P | Missense Mutation (SNP) | VAF 54/260 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- CEP76 | c.1073G>C p.G358A | Missense Mutation (SNP) | VAF 33/275 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CNTNAP2 | c.208+1G>A p.X70_splice | Splice Site (SNP) | VAF 50/395 reads (13%) | called by muse, mutect2, varscan2
- COBL | c.1766C>A p.P589H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- COG5 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 48/319 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CPS1 | c.3080G>T p.C1027F | Missense Mutation (SNP) | VAF 252/569 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CRB1 | c.1251del p.N418Ifs*34 | Frame Shift Del (DEL) | VAF 50/297 reads (17%) | called by mutect2, pindel*, varscan2
- CSMD3 | c.1250C>A p.P417H | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- DACH1 | c.2138C>G p.A713G (on ENST00000619232 / NM_001366712.1; = p.A459G on NM_004392.6) | Missense Mutation (SNP) | VAF 51/284 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- DNAJC10 | c.850-1G>A p.X284_splice | Splice Site (SNP) | VAF 44/368 reads (12%) | called by muse, mutect2, varscan2
- DSEL | c.3344C>A p.A1115E | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- DSEL | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 41/337 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DSEL | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 42/267 reads (16%) | called by muse, mutect2, varscan2
- ELL2 | c.1519A>G p.S507G | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ENAM | c.1202T>A p.L401H | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ENPP3 | c.1699C>G p.P567A | Missense Mutation (SNP) | VAF 47/312 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPC2 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- EPHA7 | c.827G>A p.C276Y | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ERN1 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 60/338 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- EXOC3 | c.1597G>T p.A533S | Missense Mutation (SNP) | VAF 35/325 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2
- FAT3 | c.10476G>C p.E3492D | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FRG2C | c.667C>A p.Q223K | Missense Mutation (SNP) | VAF 32/280 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- GABRA1 | c.370C>A p.P124T | Missense Mutation (SNP) | VAF 73/504 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GAPVD1 | c.1691G>C p.R564P | Missense Mutation (SNP) | VAF 34/298 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- GCG | c.475C>A p.L159I | Missense Mutation (SNP) | VAF 60/408 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLI3 | c.1369G>T p.G457* | Nonsense Mutation (SNP) | VAF 32/272 reads (12%) | called by muse, mutect2, varscan2
- HECTD4 | c.12835C>G p.L4279V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HECTD4 | c.1012C>G p.H338D | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HECW2 | c.1396G>C p.D466H | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HEMK1 | c.53G>A p.R18K | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- HIPK1 | c.1993G>A p.A665T | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HIVEP2 | c.1439C>G p.P480R | Missense Mutation (SNP) | VAF 39/238 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- HMCN1 | c.14128A>T p.S4710C | Missense Mutation (SNP) | VAF 67/489 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- HP | c.56T>C p.V19A | Missense Mutation (SNP) | VAF 78/447 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HSD11B1L | c.578G>T p.R193L | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- IRAG1 | c.2178G>T p.S726= | Splice Region (SNP) | VAF 49/354 reads (14%) | called by muse, mutect2, varscan2
- ITGAV | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- KATNIP | c.3423G>T p.E1141D | Missense Mutation (SNP) | VAF 44/272 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- KCNC2 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNN2 | c.1249A>G p.K417E (on ENST00000264773; = p.K629E on NM_021614.4) | Missense Mutation (SNP) | VAF 34/294 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, varscan2
- KHDC4 | c.568G>T p.A190S | Missense Mutation (SNP) | VAF 56/390 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- LAMA2 | c.6068T>A p.L2023* | Nonsense Mutation (SNP) | VAF 64/410 reads (16%) | called by muse, mutect2, varscan2
- LRP1B | c.7069G>T p.V2357L | Missense Mutation (SNP) | VAF 49/412 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- LRRC14 | c.1117A>T p.T373S | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- MAGEB17 | c.721del p.E241Sfs*44 | Frame Shift Del (DEL) | VAF 29/80 reads (36%) | called by mutect2, pindel, varscan2
- MDN1 | c.2321C>G p.S774C | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- MED13 | c.4870A>G p.I1624V | Missense Mutation (SNP) | VAF 45/227 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- MEF2D | c.429_432dup p.T145Cfs*58 | Frame Shift Ins (INS) | VAF 15/92 reads (16%) | called by mutect2, pindel, varscan2
- MFSD9 | c.625A>G p.I209V | Missense Mutation (SNP) | VAF 39/236 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MS4A14 | c.414C>A p.Y138* | Nonsense Mutation (SNP) | VAF 61/407 reads (15%) | called by muse, mutect2, varscan2
- MUC7 | c.713C>A p.P238Q | Missense Mutation (SNP) | VAF 79/613 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.168); called by muse, varscan2
- MYCBPAP | c.46A>T p.R16* | Nonsense Mutation (SNP) | VAF 36/180 reads (20%) | called by muse, mutect2, varscan2
- MYO18B | c.5671G>T p.D1891Y | Missense Mutation (SNP) | VAF 30/223 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- NPC1L1 | c.3516T>G p.I1172M | Missense Mutation (SNP) | VAF 55/369 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NPY2R | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- NTRK3 | c.197del p.N66Mfs*20 | Frame Shift Del (DEL) | VAF 18/130 reads (14%) | called by mutect2, pindel, varscan2
- NUP88 | c.1294G>C p.E432Q | Missense Mutation (SNP) | VAF 51/251 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NWD2 | c.2579G>T p.W860L | Missense Mutation (SNP) | VAF 51/242 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- NXF3 | c.890A>T p.N297I | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- OR10P1 | c.372T>A p.Y124* | Nonsense Mutation (SNP) | VAF 26/109 reads (24%) | called by muse, mutect2, varscan2
- OR13F1 | c.398C>A p.P133H | Missense Mutation (SNP) | VAF 46/245 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- OR2M5 | c.535T>C p.C179R | Missense Mutation (SNP) | VAF 39/226 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4D10 | c.440C>A p.A147D | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- OR8B2 | c.252C>A p.N84K | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- OTX2 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 40/327 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PANX3 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- PCDH11X | c.1346C>G p.S449* | Nonsense Mutation (SNP) | VAF 57/239 reads (24%) | called by muse, mutect2, varscan2
- PCDH15 | c.2101G>T p.A701S | Missense Mutation (SNP) | VAF 44/322 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- PCDHGA3 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- PCLO | c.11365G>T p.E3789* | Nonsense Mutation (SNP) | VAF 22/253 reads (9%) | called by muse, mutect2
- PCNA | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- PEX2 | c.465G>C p.L155F | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- PGBD5 | c.984G>A p.M328I (on ENST00000525115; = p.M397I on NM_001258311.2) | Missense Mutation (SNP) | VAF 45/275 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PKHD1L1 | c.11263G>T p.E3755* | Nonsense Mutation (SNP) | VAF 26/207 reads (13%) | called by muse, mutect2, varscan2
- PLP2 | c.165dup p.E56* | Frame Shift Ins (INS) | VAF 48/141 reads (34%) | called by mutect2, pindel, varscan2
- PLXNA1 | c.1646G>T p.R549L | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- POTEJ | c.1238G>A p.R413K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.02); called by mutect2, varscan2
- PRAMEF1 | c.934T>A p.C312S | Missense Mutation (SNP) | VAF 88/312 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRPF19 | c.463G>T p.G155C | Missense Mutation (SNP) | VAF 48/317 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- PTPRB | c.4228C>A p.L1410I | Missense Mutation (SNP) | VAF 104/455 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- PTPRQ | c.5903C>A p.A1968E (on ENST00000616559; = p.A1926E on NM_001145026.2) | Missense Mutation (SNP) | VAF 41/270 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- RABGGTA | c.847C>G p.L283V | Missense Mutation (SNP) | VAF 49/269 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RARS1 | c.499A>T p.R167* | Nonsense Mutation (SNP) | VAF 50/357 reads (14%) | called by muse, mutect2, varscan2
- REPS2 | c.524G>T p.R175I | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- RYR2 | c.4362C>A p.D1454E | Missense Mutation (SNP) | VAF 45/263 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- SETD1A | c.596C>A p.A199D | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- SF3A1 | c.1825C>A p.P609T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- SI | c.2881G>T p.V961L | Missense Mutation (SNP) | VAF 62/652 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- SLC13A3 | c.1700C>A p.A567E | Missense Mutation (SNP) | VAF 8/223 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- SLC16A7 | c.52T>C p.W18R | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC24A5 | c.1343C>T p.S448L | Missense Mutation (SNP) | VAF 67/364 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SLC37A4 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLCO4C1 | c.1062T>A p.H354Q | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.27); called by muse, varscan2
- SLITRK5 | c.160T>C p.C54R | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMC4 | c.2465C>G p.T822S | Missense Mutation (SNP) | VAF 133/205 reads (65%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SMU1 | c.484A>T p.M162L | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNCAIP | c.654G>C p.L218F | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- SPANXN3 | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- SPTBN2 | c.6877A>T p.K2293* | Nonsense Mutation (SNP) | VAF 51/323 reads (16%) | called by muse, mutect2, varscan2
- SRSF6 | c.52A>T p.I18F | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SUCO | c.2960C>T p.T987I | Missense Mutation (SNP) | VAF 42/311 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SULT1C3 | c.436G>T p.V146L | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- SUMF1 | c.1142A>G p.Y381C | Missense Mutation (SNP) | VAF 17/100 reads (17%) | called by muse, mutect2, varscan2
- SYNE1 | c.8177G>T p.S2726I (on ENST00000367255 / NM_182961.4; = p.S2733I on NM_033071.3) | Missense Mutation (SNP) | VAF 60/421 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TBC1D8 | c.1063A>T p.T355S | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- TEX13C | c.752del p.P251Qfs*2 | Frame Shift Del (DEL) | VAF 46/171 reads (27%) | called by mutect2, pindel, varscan2
- TMED6 | c.315G>T p.Q105H | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TMEM72 | c.472A>T p.S158C | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TMEM94 | c.195C>G p.F65L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TPRN | c.1228G>C p.A410P | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- TRAV27 | c.315C>A p.Y105* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- TRIM24 | c.682A>T p.K228* | Nonsense Mutation (SNP) | VAF 63/367 reads (17%) | called by muse, mutect2, varscan2
- TRIOBP | c.6190G>T p.G2064C (on ENST00000644935 / NM_001039141.3; = p.G351C on NM_007032.5) | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- TRMT1L | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 34/295 reads (12%) | called by muse, mutect2, varscan2
- TRPC7 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 17/153 reads (11%) | called by muse, mutect2, varscan2
- TSSC4 | c.359G>C p.G120A | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- TTC5 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 47/334 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TTN | c.84172A>G p.T28058A (on ENST00000591111; = p.T20634A on NM_003319.4) | Missense Mutation (SNP) | VAF 14/113 reads (12%) | PolyPhen benign (0.124); called by muse, mutect2, varscan2
- UBE3A | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBXN2B | c.108A>C p.E36D | Missense Mutation (SNP) | VAF 44/304 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- USH2A | c.5999C>T p.P2000L | Missense Mutation (SNP) | VAF 59/338 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- VPS13B | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 40/365 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ZNF17 | c.833A>T p.E278V | Missense Mutation (SNP) | VAF 91/233 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF26 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 66/313 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF441 | c.1383C>A p.Y461* | Nonsense Mutation (SNP) | VAF 38/182 reads (21%) | called by muse, mutect2, varscan2
- ZNF469 | c.8732T>G p.L2911R (on ENST00000437464; = p.L2939R on NM_001367624.2) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- ZNF850 | c.308G>T p.W103L | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0.03); called by muse, mutect2
- ABCC6 | c.2454C>A p.P818= | Silent (SNP) | VAF 30/164 reads (18%) | catalogued as COSV99229052; called by muse, mutect2, varscan2
- ABTB2 | c.624T>G p.G208= | Silent (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2, varscan2
- AKR1C4 | c.195C>T p.I65= | Silent (SNP) | VAF 27/205 reads (13%) | called by muse, mutect2, varscan2
- ANO4 | c.1665G>T p.V555= (on ENST00000392977 / NM_001286615.2; = p.V520= on NM_178826.4) | Silent (SNP) | VAF 19/170 reads (11%) | called by muse, mutect2, varscan2
- ARHGAP40 | c.408G>A p.S136= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as rs546002152, COSV54805571; called by muse, mutect2, varscan2
- ARHGEF38 | c.192A>G p.L64= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as rs761508955; called by muse, mutect2
- ATP7A | c.2592A>G p.E864= | Silent (SNP) | VAF 43/138 reads (31%) | called by muse, mutect2, varscan2
- CAMTA1 | c.1710G>A p.P570= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs372631678; called by muse, mutect2, varscan2
- CLASP1 | c.1005G>A p.K335= | Silent (SNP) | VAF 59/411 reads (14%) | called by muse, mutect2, varscan2
- CPNE4 | c.1360C>A p.R454= | Silent (SNP) | VAF 22/124 reads (18%) | catalogued as rs758874490, COSV104436661; called by muse, mutect2, varscan2
- CUX2 | c.549G>A p.A183= | Silent (SNP) | VAF 25/160 reads (16%) | catalogued as rs764837086; called by muse, mutect2, varscan2
- DNAH5 | c.5955C>A p.G1985= | Silent (SNP) | VAF 37/310 reads (12%) | catalogued as rs141369170; called by muse, mutect2, varscan2
- EYA1 | c.228A>G p.P76= | Silent (SNP) | VAF 99/647 reads (15%) | called by muse, mutect2, varscan2
- FAM20A | c.1572C>T p.D524= | Silent (SNP) | VAF 22/137 reads (16%) | catalogued as rs780208759, COSV56835459; called by muse, mutect2, varscan2
- FAM214A | c.2088G>A p.L696= | Silent (SNP) | VAF 24/169 reads (14%) | called by muse, mutect2, varscan2
- FAM71B | c.1077G>A p.S359= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as rs369213663, COSV57228490; called by muse, mutect2, varscan2
- FCRL5 | c.2790C>T p.I930= | Silent (SNP) | VAF 35/249 reads (14%) | called by muse, mutect2, varscan2
- FSCB | c.1626T>A p.A542= | Silent (SNP) | VAF 18/146 reads (12%) | called by muse, mutect2, varscan2
- GABBR2 | c.2109C>T p.C703= | Silent (SNP) | VAF 97/502 reads (19%) | called by muse, mutect2, varscan2
- GAP43 | c.390C>T p.S130= | Silent (SNP) | VAF 12/93 reads (13%) | called by muse, mutect2, varscan2
- GPRASP1 | c.3846C>T p.L1282= | Silent (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- GRIA1 | c.309C>A p.A103= | Silent (SNP) | VAF 82/489 reads (17%) | called by muse, mutect2, varscan2
- GRIN2B | c.117C>T p.V39= | Silent (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- HAGH | c.882G>A p.R294= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs769848135; called by muse, mutect2
- IFT140 | c.1689G>A p.A563= | Silent (SNP) | VAF 27/190 reads (14%) | catalogued as rs774761227; called by muse, mutect2, varscan2
- IGF2R | c.5916G>A p.V1972= | Silent (SNP) | VAF 66/375 reads (18%) | catalogued as rs1389773335, COSV63633814; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.21C>A p.I7= | Silent (SNP) | VAF 20/210 reads (10%) | called by muse, mutect2
- IGKV3-11 | c.183C>T p.G61= | Silent (SNP) | VAF 111/559 reads (20%) | catalogued as rs565432335; called by muse, mutect2, varscan2
- IGKV3-7 | c.246G>A p.R82= | Silent (SNP) | VAF 98/399 reads (25%) | called by muse, mutect2, varscan2
- IL10RA | c.1089C>A p.G363= | Silent (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- KIFAP3 | c.786A>G p.E262= | Silent (SNP) | VAF 24/224 reads (11%) | called by muse, mutect2, varscan2
- LCMT2 | c.1038C>T p.V346= | Silent (SNP) | VAF 43/275 reads (16%) | catalogued as rs1032799097; called by muse, mutect2, varscan2
- MALRD1 | c.2313C>A p.G771= | Silent (SNP) | VAF 42/271 reads (15%) | catalogued as COSV66000691; called by muse, mutect2, varscan2
- MORN1 | c.1485G>T p.A495= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs372417316; called by muse, mutect2, varscan2
- MYH2 | c.1119G>A p.E373= | Silent (SNP) | VAF 52/423 reads (12%) | called by muse, mutect2, varscan2
- MYH8 | c.78G>A p.R26= | Silent (SNP) | VAF 89/483 reads (18%) | catalogued as COSV67961563; called by muse, mutect2, varscan2
- MYO10 | c.6021G>T p.A2007= | Silent (SNP) | VAF 31/171 reads (18%) | called by muse, mutect2, varscan2
- MZB1 | c.87C>T p.A29= | Silent (SNP) | VAF 26/187 reads (14%) | catalogued as rs1181097908; called by muse, varscan2
- OR2T2 | c.594C>A p.T198= | Silent (SNP) | VAF 64/476 reads (13%) | called by muse, mutect2, varscan2
- OR4C15 | c.762C>A p.I254= (on ENST00000314644; = p.I200= on NM_001001920.2) | Silent (SNP) | VAF 40/250 reads (16%) | catalogued as COSV58952941, COSV58953829; called by muse, mutect2, varscan2
- PAPPA2 | c.2940C>T p.V980= | Silent (SNP) | VAF 43/309 reads (14%) | catalogued as COSV62806678; called by muse, mutect2, varscan2
- PIK3C2B | c.2937G>T p.L979= | Silent (SNP) | VAF 25/313 reads (8%) | called by muse, mutect2
- PLXDC2 | c.390T>C p.D130= | Silent (SNP) | VAF 42/243 reads (17%) | catalogued as COSV101022575; called by muse, mutect2, varscan2
- PRDM14 | c.819T>C p.F273= | Silent (SNP) | VAF 37/298 reads (12%) | called by muse, mutect2, varscan2
- PRDM9 | c.2265G>T p.R755= | Silent (SNP) | VAF 102/429 reads (24%) | catalogued as COSV99689949; called by muse, varscan2
- RABL6 | c.654C>T p.F218= | Silent (SNP) | VAF 55/328 reads (17%) | catalogued as rs568788847; called by muse, mutect2, varscan2
- SEMA5A | c.3024C>A p.P1008= | Silent (SNP) | VAF 70/420 reads (17%) | catalogued as COSV66792404; called by muse, mutect2, varscan2
- SEPTIN6 | c.909G>C p.L303= | Silent (SNP) | VAF 46/142 reads (32%) | called by muse, varscan2
- SLC5A8 | c.1689C>A p.S563= | Silent (SNP) | VAF 56/406 reads (14%) | catalogued as COSV101610526; called by muse, mutect2, varscan2
- SLC9A4 | c.1959C>A p.T653= | Silent (SNP) | VAF 39/270 reads (14%) | called by muse, mutect2, varscan2
- SOX6 | c.1365T>C p.P455= (on ENST00000528429 / NM_001145819.2; = p.P414= on NM_017508.3) | Silent (SNP) | VAF 59/402 reads (15%) | called by muse, mutect2, varscan2
- STRN3 | c.1344G>C p.T448= (on ENST00000357479 / NM_001083893.2; = p.T364= on NM_014574.4) | Silent (SNP) | VAF 74/379 reads (20%) | catalogued as rs753241184; called by muse, mutect2, varscan2
- SYNE1 | c.8316G>T p.L2772= (on ENST00000367255 / NM_182961.4; = p.L2779= on NM_033071.3) | Silent (SNP) | VAF 95/719 reads (13%) | called by muse, mutect2, varscan2
- TRANK1 | c.4668G>T p.L1556= | Silent (SNP) | VAF 37/274 reads (14%) | called by muse, mutect2, varscan2
- UNC80 | c.8356C>T p.L2786= | Silent (SNP) | VAF 20/142 reads (14%) | called by muse, varscan2
- UTF1 | c.936C>A p.G312= | Silent (SNP) | VAF 15/77 reads (19%) | called by muse, mutect2, varscan2
- VAV2 | c.90C>G p.V30= | Silent (SNP) | VAF 13/76 reads (17%) | called by muse, mutect2, varscan2
- ZNF280B | c.858T>C p.S286= | Silent (SNP) | VAF 63/420 reads (15%) | catalogued as rs1365026790, COSV64528824; called by muse, mutect2, varscan2
- ZNF804B | c.873T>C p.V291= | Silent (SNP) | VAF 18/139 reads (13%) | catalogued as rs1325287344; called by muse, mutect2, varscan2
- ZNF830 | c.315G>T p.A105= | Silent (SNP) | VAF 48/295 reads (16%) | called by muse, mutect2, varscan2
- ZRANB1 | c.726G>A p.K242= | Silent (SNP) | VAF 66/436 reads (15%) | called by muse, varscan2
- AC009093.9 | n.569A>T | RNA (SNP) | VAF 51/461 reads (11%) | called by muse, mutect2, varscan2
- AC073348.1 | n.290G>C | RNA (SNP) | VAF 16/98 reads (16%) | called by muse, mutect2
- AC073648.1 | n.467T>C | RNA (SNP) | VAF 22/115 reads (19%) | catalogued as rs1221152978; called by mutect2, varscan2
- ADGRE4P | n.1398G>A | RNA (SNP) | VAF 16/85 reads (19%) | catalogued as rs1447721267; called by muse, mutect2, varscan2
- AGAP7P | n.1137C>A | RNA (SNP) | VAF 89/849 reads (10%) | called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826754 C>T | 3'Flank (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
- ANO4 | c.-69C>T | 5'UTR (SNP) | VAF 48/277 reads (17%) | called by muse, mutect2, varscan2
- BCHE | c.-95G>T | 5'UTR (SNP) | VAF 36/453 reads (8%) | called by muse, mutect2
- BMS1P1 | chr10:46816738 G>T | 3'Flank (SNP) | VAF 74/572 reads (13%) | called by muse, mutect2, varscan2
- CHD6 | c.-23-12682G>A | Intron (SNP) | VAF 42/222 reads (19%) | called by muse, mutect2, varscan2
- COL7A1 | c.7104+29G>A | Intron (SNP) | VAF 45/190 reads (24%) | called by muse, mutect2, varscan2
- CTBP2 | c.58+12443G>T | Intron (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2
- ERBB4 | c.1872-164G>C | Intron (SNP) | VAF 164/518 reads (32%) | catalogued as COSV53544807; called by muse, mutect2, varscan2
- FAM153A | c.-18G>T | 5'UTR (SNP) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- FHL1 | c.*695T>A | 3'UTR (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2, varscan2
- GP6 | c.*254C>A | 3'UTR (SNP) | VAF 91/220 reads (41%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1571A>C | RNA (SNP) | VAF 23/220 reads (10%) | called by mutect2, varscan2
- LINC02448 | n.279G>T | RNA (SNP) | VAF 38/327 reads (12%) | called by muse, mutect2, varscan2
- LPIN2 | c.590+4824A>G | Intron (SNP) | VAF 125/732 reads (17%) | called by muse, mutect2, varscan2
- METTL6 | c.531+219C>T | Intron (SNP) | VAF 49/255 reads (19%) | called by muse, mutect2, varscan2
- MIR6511B2 | chr16:15130722 T>A | 3'Flank (SNP) | VAF 55/238 reads (23%) | called by muse, mutect2, varscan2
- MTHFD2L | chr4:74157871 T>C | 5'Flank (SNP) | VAF 27/165 reads (16%) | called by muse, mutect2, varscan2
- NBPF22P | n.911G>C | RNA (SNP) | VAF 56/394 reads (14%) | called by muse, mutect2
- NEK1 | c.*14T>G | 3'UTR (SNP) | VAF 48/168 reads (29%) | called by muse, mutect2, varscan2
- NOL4L-DT | n.214G>A | RNA (SNP) | VAF 45/280 reads (16%) | catalogued as rs79470348; called by muse, mutect2, varscan2
- OR2W5 | n.1251C>A | RNA (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- PDE4B | c.281+74246A>T | Intron (SNP) | VAF 53/290 reads (18%) | called by muse, mutect2, varscan2
- PTGER3 | c.*37G>T | 3'UTR (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- QTRT1 | c.786-10G>T | Intron (SNP) | VAF 19/95 reads (20%) | called by muse, mutect2, varscan2
- RNY4P30 | chr13:49892541 G>A | 5'Flank (SNP) | VAF 40/202 reads (20%) | catalogued as rs771158959; called by muse, mutect2, varscan2
- ROR2 | chr9:91722554 C>T | 3'Flank (SNP) | VAF 52/298 reads (17%) | called by muse, mutect2, varscan2
- SAC3D1 | c.-7-15A>T | Intron (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- SNORD115-35 | n.21G>T | RNA (SNP) | VAF 46/283 reads (16%) | called by muse, mutect2, varscan2
- SNORD115-35 | n.22T>G | RNA (SNP) | VAF 46/285 reads (16%) | called by muse, mutect2, varscan2
- TGFB1I1 | c.13+12C>T | Intron (SNP) | VAF 5/16 reads (31%) | catalogued as rs1390624298; called by muse, mutect2, varscan2
- TPP1 | c.688-19G>T | Intron (SNP) | VAF 59/444 reads (13%) | called by muse, mutect2, varscan2
- TRIM23 | c.*377G>A | 3'UTR (SNP) | VAF 40/285 reads (14%) | called by muse, mutect2, varscan2
- UQCRB | c.*4109A>G | 3'UTR (SNP) | VAF 52/272 reads (19%) | called by muse, mutect2, varscan2
- WFDC3 | c.*35C>T | 3'UTR (SNP) | VAF 37/197 reads (19%) | called by muse, mutect2, varscan2
- ZNF454 | chr5:178969540 G>T | 3'Flank (SNP) | VAF 61/360 reads (17%) | catalogued as rs1389925811; called by muse, mutect2, varscan2
- ZNF668 | c.-22-140A>T | Intron (SNP) | VAF 44/260 reads (17%) | called by muse, mutect2, varscan2
